EXCEPTIONAL_RESPONDERS case ER-AC6N — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/94825b57-e507-431a-9c37-d517add300e7

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1952; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Classification of tumor: metastasis; Age at diagnosis: 56.3 years (20,572 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC clinical stage: Stage IV; Prior malignancy: no; Days to last follow up: 2,001 days (5.5 years); Days to best overall response: 112 days; Best overall response: Partial Response.
   Treatment given: Therapeutic agents: Cisplatin; Days to treatment start: 34 days; Days to treatment end: 117 days.
   Treatment given: Therapeutic agents: Pemetrexed; Days to treatment start: 34 days; Days to treatment end: 1,953 days (5.3 years).

Follow-up (1 entry)
- Days to follow up: 2,001 days (5.5 years); Disease response: Clinical Progression; Progression or recurrence: Yes; Days to progression: 2,001 days (5.5 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-AC6N-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-AC6N-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 60; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
